Somatic mutation profile of tumor specimen TCGA-DD-AAVS-01A (aliquot TCGA-DD-AAVS-01A-11D-A40R-10) from TCGA case TCGA-DD-AAVS, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 56.4 years (20,586 days).
Specimen TCGA-DD-AAVS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4135f40f-5a68-42ed-84e6-69fa67862177.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAVS-10A (Blood Derived Normal), aliquot TCGA-DD-AAVS-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dbe6869-2b42-414c-8e8e-f7f4692650db

The open-access MAF lists 58 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 11, Nonsense Mutation 4, Frame Shift Del 2, RNA 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL3 | c.910A>T p.R304W (on ENST00000506720 / NM_001322402.2; = p.R236W on NM_015236.6) | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101547297; called by muse, mutect2
- AHDC1 | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.142); catalogued as COSV99899562; called by muse, mutect2, varscan2
- ALOX15B | c.1938G>C p.Q646H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV101205660; called by muse, mutect2, varscan2
- ATAD2B | c.2486G>A p.S829N | Missense Mutation (SNP) | VAF 111/307 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV99478134; called by muse, mutect2, varscan2
- AXIN1 | c.1189G>T p.E397* | Nonsense Mutation (SNP) | VAF 41/65 reads (63%) | catalogued as COSV99250109; called by muse, mutect2, varscan2
- BTAF1 | c.2287T>C p.Y763H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99795586; called by muse, mutect2, varscan2
- CENATAC | c.859G>C p.D287H | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100548834; called by muse, mutect2, varscan2
- CFC1 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 143/904 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.067); catalogued as COSV52090933, COSV99383500; called by muse, varscan2
- CRX | c.429T>A p.S143R | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as CX078211, COSV99704597; called by muse, mutect2, varscan2
- CTNNA2 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV63576527; called by muse, mutect2, varscan2
- DSP | c.3674C>G p.S1225C | Missense Mutation (SNP) | VAF 187/289 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV101131528; called by muse, mutect2, varscan2
- EGFLAM | c.1868C>G p.P623R | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as rs370628892, COSV100380521; called by muse, mutect2, varscan2
- FNIP1 | c.1390C>T p.L464F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100330522; called by muse, mutect2, varscan2
- GREB1 | c.5254G>T p.A1752S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.205); catalogued as COSV99303380; called by muse, mutect2, varscan2
- HEYL | c.345C>A p.D115E | Missense Mutation (SNP) | VAF 51/81 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100865321; called by muse, mutect2, varscan2
- IFT57 | c.789C>G p.I263M | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.587); catalogued as COSV99197856; called by muse, mutect2, varscan2
- IRF2 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753833490, COSV66930359; called by muse, mutect2, varscan2
- IRX1 | c.1332G>T p.R444S | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV100116647; called by muse, mutect2, varscan2
- LGI4 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1054775133, COSV100032763; called by muse, mutect2, varscan2
- LRP1B | c.7624G>A p.E2542K | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67259269, COSV67264281; called by muse, mutect2, varscan2
- MELK | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53203337, COSV99974871, COSV99975099; called by muse, mutect2, varscan2
- MUC16 | c.13312G>A p.D4438N | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.028); catalogued as COSV101200546; called by muse, mutect2, varscan2
- OR52B4 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs267602877, COSV68768715; called by muse, mutect2, varscan2
- PAK5 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV100781554; called by muse, mutect2, varscan2
- PCDHA1 | c.1052del p.A351Gfs*35 | Frame Shift Del (DEL) | VAF 45/157 reads (29%) | catalogued as COSV65374531; called by mutect2, pindel, varscan2
- PLEKHA3 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 82/311 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV99317829; called by muse, mutect2, varscan2
- REG1A | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs142176788, COSV52071405; called by muse, mutect2, varscan2
- RFX7 | c.1573A>G p.I525V (on ENST00000559447 / NM_001368074.1; = p.I622V on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1257291850, COSV100429089; called by muse, mutect2, varscan2
- RP9 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.148); catalogued as rs1361076660, COSV51807467; called by muse, mutect2
- SLC17A4 | c.1088T>A p.L363H | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100930639; called by muse, mutect2, varscan2
- SNX27 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 60/227 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as COSV64325838; called by muse, mutect2, varscan2
- SPEG | c.7830C>A p.C2610* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100405124; called by muse, mutect2, varscan2
- SRRM3 | c.665G>T p.R222I | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58386519; called by muse, mutect2, varscan2
- TAF9B | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 160/211 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557250202, COSV100540733; called by muse, mutect2, varscan2
- TAS2R50 | c.473A>G p.Y158C | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs1421453034, COSV101115230; called by muse, mutect2, varscan2
- TMEM241 | c.122G>A p.W41* | Nonsense Mutation (SNP) | VAF 31/74 reads (42%) | catalogued as COSV101271767; called by muse, mutect2, varscan2
- TMPRSS9 | c.1502G>A p.S501N (on ENST00000648592; = p.S467N on NM_182973.2) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs750844598, COSV100211550; called by muse, mutect2, varscan2
- TNIP1 | c.1402A>G p.I468V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100161607; called by muse, mutect2, varscan2
- TSEN54 | c.1384C>T p.R462* | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | catalogued as rs201775186, COSV99390135; called by muse, mutect2, varscan2
- TSSC4 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.076); catalogued as COSV99330350; called by muse, mutect2, varscan2
- VSTM4 | c.791C>A p.T264K | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.03); catalogued as COSV100251938, COSV60525001; called by muse, mutect2, varscan2
- ZNF830 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100030876; called by muse, mutect2, varscan2
- HSD11B1 | c.189del p.T64Qfs*33 | Frame Shift Del (DEL) | VAF 17/121 reads (14%) | called by mutect2, pindel, varscan2
- MYOM1 | c.795dup p.A266Cfs*5 | Frame Shift Ins (INS) | VAF 25/94 reads (27%) | called by mutect2, pindel, varscan2
- CDH19 | c.783C>T p.Y261= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs1298743984, COSV50977885; called by muse, mutect2, varscan2
- CTLA4 | c.468G>A p.P156= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs200657280; ClinVar: likely benign; called by muse, mutect2, varscan2
- HERC1 | c.13482G>A p.A4494= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs751845469, COSV101496742; called by muse, mutect2, varscan2
- NPAS3 | c.2424G>A p.R808= (on ENST00000356141 / NM_001164749.2; = p.R776= on NM_022123.3) | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100640431; called by muse, mutect2
- NRP1 | c.1182A>G p.V394= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as COSV55162532; called by muse, mutect2, varscan2
- POLR1E | c.390C>A p.S130= (on ENST00000377792 / NM_001282766.1; = p.S68= on NM_022490.4) | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as rs1234611290, COSV100905420; called by muse, mutect2, varscan2
- RASA3 | c.507C>T p.T169= | Silent (SNP) | VAF 61/217 reads (28%) | catalogued as rs141276378, COSV61863451; called by muse, mutect2, varscan2
- RNF167 | c.819G>A p.Q273= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as COSV99337482; called by muse, mutect2, varscan2
- SLC25A12 | c.1854A>G p.E618= | Silent (SNP) | VAF 47/204 reads (23%) | catalogued as COSV99785248; called by muse, mutect2, varscan2
- SV2A | c.306C>T p.P102= | Silent (SNP) | VAF 70/122 reads (57%) | catalogued as COSV100975219; called by muse, mutect2, varscan2
- WNK4 | c.2610C>A p.P870= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as COSV99890972; called by muse, mutect2, varscan2
- GTF2H2B | n.1153G>A | RNA (SNP) | VAF 52/242 reads (21%) | called by muse, varscan2
- PRUNE2 | c.756+24G>T | Intron (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- ZNF658B | n.1176A>G | RNA (SNP) | VAF 74/162 reads (46%) | called by muse, mutect2, varscan2
